Somatic mutation profile of tumor specimen TCGA-AB-2882-03A (aliquot TCGA-AB-2882-03A-01W-0761-09) from TCGA case TCGA-AB-2882, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.5 years (26,844 days).
Specimen TCGA-AB-2882-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91556111-15d5-49ed-9596-b3b6f3b2c1be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2882-11A (Solid Tissue Normal), aliquot TCGA-AB-2882-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efebcf20-77ba-4a65-90ef-c3c0c7aad0c8

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Missense Mutation 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH17 | c.6600G>A p.W2200* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101102287; called by mutect2, varscan2
- SCAF8 | c.3331G>T p.G1111C | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV100914098; called by muse, mutect2, varscan2
- CADPS | c.2613G>C p.R871= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1352502514, COSV99338155; called by muse, mutect2, varscan2
- EEF2 | c.613-146T>A | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100500751; called by muse, mutect2, varscan2
